Gene-level copy-number profile of tumor specimen HCM-CSHL-0727-C18-06A from HCMI case HCM-CSHL-0727-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 63.1 years (23,063 days).
Specimen HCM-CSHL-0727-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c259832-026d-4e60-8f9e-890a9a6d3ae0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0727-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/86f2eab8-e667-407c-a06e-8bfef1f1d0c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 14,742; copy number 2: 40,478; copy number 3: 1,820; copy number 4: 1,160; copy number 5: 75; copy number 6: 84; copy number 7: 7.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:68,509,441–68,670,652, 5 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.3, UGT2B15.
- chr6:162,568,379–162,569,728, 1 gene (within-gene range 0–2): KRT8P44.
- chr14:20,891,399–20,936,255, 4 genes: RNASE3, AL355922.4, AL355922.3, AL355922.1.
- chr14:38,256,202–38,728,481, 3 genes (within-gene range 0–1): AL355835.1, AL357094.1, KRT8P1.
- chr17:46,372,855–46,555,650, 3 genes (within-gene range 0–2): NSFP1, RDM1P2, LRRC37A2.
- chr17:46,537,534–46,537,814, 1 gene (within-gene range 0–2): RN7SL199P.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–3): AL138808.1, RNU6-1159P, RNU6-115P.
- chr22:18,846,811–18,894,407, 4 genes: AC008132.1, BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 166 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,269,491–38,311,808, 7 genes, copy number 7 (within-gene range 3–7): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr13:70,564,267–75,859,870, 56 genes, copy number 6: AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP.
- chr13:88,142,867–93,227,317, 50 genes, copy number 5–6 (within-gene range 4–6): LINC00373, RPL29P29, LINC00433, AL445984.2, LINC00560, GRPEL2P1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.1.
- chr14:22,163,238–22,502,292, 52 genes, copy number 5: TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 14,740. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
